Somatic mutation profile of tumor specimen TCGA-ET-A25K-01A (aliquot TCGA-ET-A25K-01A-11D-A16O-08) from TCGA case TCGA-ET-A25K, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 36.6 years (13,351 days).
Specimen TCGA-ET-A25K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b189e639-7572-4d0f-b603-93ab9e1c5c2b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A25K-10A (Blood Derived Normal), aliquot TCGA-ET-A25K-10A-01D-A16O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/990496ce-07b1-4737-9da8-0810359740e6

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- FHL5 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV58735696; called by muse, mutect2
- KIF1B | c.3151A>G p.M1051V (on ENST00000377086 / NM_001365952.1; = p.M1005V on NM_015074.3) | Missense Mutation (SNP) | VAF 60/196 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs765659089, COSV55811000; called by muse, mutect2, varscan2
- TTN | c.56257A>C p.K18753Q (on ENST00000591111; = p.K11329Q on NM_003319.4) | Missense Mutation (SNP) | VAF 57/159 reads (36%) | PolyPhen probably damaging (0.997); catalogued as COSV60159000; called by muse, mutect2, varscan2
- CSMD2 | c.2670C>T p.T890= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV53927136; called by muse, mutect2
- RANBP2 | c.5499T>G p.S1833= | Silent (SNP) | VAF 29/98 reads (30%) | catalogued as COSV51703288; called by muse, mutect2, varscan2
